Somatic mutation profile of tumor specimen TCGA-ZG-A9L2-01A (aliquot TCGA-ZG-A9L2-01A-31D-A41K-08) from TCGA case TCGA-ZG-A9L2, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 70.0 years (25,573 days).
Specimen TCGA-ZG-A9L2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) efba81b1-ffde-4153-8a34-85fe8391ea2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZG-A9L2-10A (Blood Derived Normal), aliquot TCGA-ZG-A9L2-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e161a0d0-cf94-4b83-b67c-7fef164cf81b

The open-access MAF lists 23 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Frame Shift Ins 3, Frame Shift Del 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.2510C>T p.T837I | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.297); catalogued as COSV99714427; called by muse, mutect2, varscan2
- ANKRD28 | c.1354C>G p.Q452E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.61); catalogued as COSV101080944; called by muse, mutect2, varscan2
- ASB4 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs267601648, COSV57946501; called by muse, mutect2, varscan2
- CHIA | c.1292C>T p.A431V (on ENST00000343320; = p.A323V on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.21); catalogued as COSV100588669; called by muse, mutect2, varscan2
- DPPA5 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.059); catalogued as rs1462976045, COSV64875424; called by muse, mutect2, varscan2
- HSF5 | c.593A>C p.D198A | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100090806; called by muse, mutect2, varscan2
- KARS1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100094544; called by muse, mutect2, varscan2
- LCE1D | c.307G>A p.G103S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | PolyPhen possibly damaging (0.659); catalogued as rs1468360393, COSV58270476; called by muse, mutect2, varscan2
- NDUFA12 | c.167T>C p.F56S | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV100580901, COSV59845485; called by muse, mutect2, varscan2
- PCDHGA3 | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV53909310, COSV99547028; called by muse, mutect2, varscan2
- PCDHGA3 | c.74A>T p.E25V | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as COSV99547030; called by muse, mutect2, varscan2
- PTEN | c.113del p.P38Lfs*16 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as COSV100911304, COSV64289791; called by mutect2, pindel, varscan2
- SERINC3 | c.263A>T p.D88V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as COSV99667998; called by muse, mutect2
- SMARCA4 | c.3640A>C p.I1214L | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV100759122, COSV60804834; called by muse, mutect2, varscan2
- CYP3A4 | c.410_417del p.F137Wfs*47 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel
- CYSLTR1 | c.967_968dup p.K324Rfs*67 | Frame Shift Ins (INS) | VAF 11/29 reads (38%) | called by mutect2, pindel, varscan2
- EEF1A1 | c.862_877del p.E288Kfs*7 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel, varscan2
- EMC3 | c.592dup p.M198Nfs*39 | Frame Shift Ins (INS) | VAF 16/84 reads (19%) | called by mutect2, pindel, varscan2
- OTC | c.258dup p.E87* | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- ALMS1 | c.8400T>A p.V2800= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100043762; called by muse, mutect2, varscan2
- COPG1 | c.1932G>A p.T644= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs563330778, COSV100135482; called by muse, mutect2, varscan2
- SASH1 | c.2679A>T p.L893= | Silent (SNP) | VAF 34/164 reads (21%) | catalogued as COSV100821448; called by muse, mutect2, varscan2
- IFRD2 | chr3:50292633 G>A | 5'Flank (SNP) | VAF 13/64 reads (20%) | catalogued as rs1553710078, COSV100269819; called by muse, mutect2, varscan2
